Gene-level copy-number profile of tumor specimen TARGET-40-PASEFS-01A from TARGET case TARGET-40-PASEFS, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 18.1 years (6,625 days).
Specimen TARGET-40-PASEFS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.7affb496-0c65-53bc-97e6-798802c9251a.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PASEFS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 421 have no estimate.
https://portal.gdc.cancer.gov/files/cfab6ac8-2b6d-4756-8641-64191af0473c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 71; copy number 1: 1,199; copy number 2: 6,417; copy number 3: 4,448; copy number 4: 27,598; copy number 5: 6,446; copy number 6: 9,128; copy number 7: 1,361; copy number 8: 1,281; copy number 9: 567; copy number 10: 1,575; copy number 11: 23; copy number 12: 87; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 58 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:115,802,363–117,139,389, 3 genes (within-gene range 0–4): LSAMP, RN7SL815P, LSAMP-AS1.
- chr5:165,349,030–165,778,689, 2 genes (within-gene range 0–5): AC008415.1, RN7SKP60.
- chr5:165,905,126–167,168,401, 7 genes: AC008489.1, RPL7P20, AC114321.1, AC026403.1, LINC01947, AC091819.2, AC091819.1.
- chr5:167,287,320–167,729,124, 5 genes: AC091820.2, AC091820.1, AC008601.1, AC008708.2, AC008708.1.
- chr5:168,033,091–168,033,205, 1 gene: AC008705.1.
- chr10:44,712–254,637, 6 genes: AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297.
- chr10:282,015–282,125, 1 gene: RNA5SP298.
- chr11:84,997,226–86,295,576, 23 genes: AP000857.1, HNRNPCP6, AP002803.1, AP003035.1, RNU6-1292P, TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17.
- chr11:131,370,478–132,336,822, 1 gene (within-gene range 0–4): NTM.
- chr11:131,622,451–131,984,661, 4 genes (within-gene range 0–3): NTM-AS1, AP004372.1, AP000844.2, AP000844.1.
- chr13:76,552,807–76,846,594, 3 genes: AL136441.1, AL161717.1, AL365394.1.
- chr14:79,661,666–79,974,169, 2 genes (within-gene range 0–2): AC008056.1, AF123462.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,253 genes in 79 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:12,598,987–13,331,683, 7 genes, copy number 9 (within-gene range 4–9): AC096559.1, AC009486.2, AC009486.1, TRIB2, MIR3125, AC064875.1, AC093912.1.
- chr2:26,950,308–27,635,174, 44 genes, copy number 10 (within-gene range 4–10): AC013472.1, MAPRE3, MAPRE3-AS1, TMEM214, AGBL5, AGBL5-AS1, AC013472.2, AGBL5-IT1, AC013403.2, OST4, EMILIN1, KHK, CGREF1, ABHD1, PREB, PRR30, TCF23, AC013403.1, SLC5A6, ATRAID, CAD, SLC30A3, DNAJC5G, TRIM54, UCN, MPV17, GTF3C2, GTF3C2-AS1, AC074117.1, EIF2B4, SNX17, ZNF513, PPM1G, FTH1P3, NRBP1, KRTCAP3, IFT172, AC074117.2, RNU6-986P, FNDC4, GCKR, C2orf16, ZNF512, AC074091.2.
- chr2:31,793,823–33,657,460, 40 genes, copy number 9: LINC01946, KRT18P52, AK2P2, AL121652.1, MEMO1, DPY30, AL121655.1, SPAST, AL121658.1, SLC30A6, DDX50P1, RNU6-647P, NLRC4, YIPF4, AL133245.1, BIRC6, BIRC6-AS1, AL133243.2, AL133243.3, MIR558, AL133243.1, BIRC6-AS2, AL133243.4, TTC27, MIR4765, LINC00486, LINC00486, Y_RNA, LTBP1, H2ACP2, AC019127.1, RNA5SP91, RNA5SP92, MIR4430, RASGRP3, RASGRP3-AS1, FAM98A, AC017050.1, ATP6V0E1P3, HNRNPA1P61.
- chr2:56,147,630–57,049,336, 6 genes, copy number 9: AC007744.1, AC007743.1, CCDC85A, RNA5SP93, PPIAP63, EIF2S2P7.
- chr2:64,606,975–65,130,331, 16 genes, copy number 9: LINC02579, SERTAD2, AC007365.1, RPS10P9, RN7SL341P, Y_RNA, AC007880.1, LINC01800, LINC02245, RN7SL211P, RPL11P1, SLC1A4, RNU6-548P, LINC02576, CEP68, RAB1A.
- chr2:66,433,452–67,041,966, 9 genes, copy number 9 (within-gene range 4–9): MEIS1, MEIS1-AS2, LINC01798, LINC01797, DNMT3AP1, AC009474.1, LINC01799, LINC01628, AC007403.1.
- chr2:69,181,897–69,905,575, 17 genes, copy number 9: RNA5SP96, RNU6-1216P, AC112230.1, GFPT1, Y_RNA, NFU1, AAK1, RN7SL604P, SNORA36C, RPL36AP16, B3GALNT1P1, ANXA4, AC092431.1, GMCL1, AC019206.1, RPL23AP92, SNRNP27.
- chr2:85,537,462–85,728,337, 14 genes, copy number 9: PARTICL, MAT2A, GGCX, VAMP8, RN7SL126P, VAMP5, RNF181, TMEM150A, USP39, C2orf68, SFTPB, GNLY, GPR160P1, RNU1-38P.
- chr2:100,208,254–100,996,829, 18 genes, copy number 9 (within-gene range 4–9): LINC01104, LONRF2, CYCSP7, AC012493.1, CHST10, RALBP1P2, NMS, ARPP19P2, PDCL3, HMGN2P22, LINC01849, AC092845.1, NANOGNBP1, LINC01868, AC092168.1, AC092168.3, NPAS2, AC092168.2.
- chr2:102,187,006–102,533,972, 10 genes, copy number 9 (within-gene range 4–9): IL1RL2, FAM183DP, IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1, SLC9A4.
- chr2:111,865,798–112,434,488, 17 genes, copy number 9 (within-gene range 4–9): AC093166.2, EEF1E1P1, MERTK, RN7SL297P, RTRAFP1, SLC30A6P1, AC093675.1, TMEM87B, AC093675.2, FBLN7, AC092645.1, ZC3H8, AC092645.2, ZC3H6, NDUFB4P6, AC115115.1, RGPD8.
- chr2:199,760,544–200,008,540, 7 genes, copy number 11 (within-gene range 5–11): FTCDNL1, AC097717.1, AC108032.1, RN7SL717P, C2orf69, TYW5, MAIP1.
- chr2:201,487,421–201,927,543, 19 genes, copy number 10 (within-gene range 5–10): C2CD6, MTCO2P16, MTATP6P16, MTCO3P16, MTND3P16, MTND4LP16, MTND4P29, MTND5P31, TMEM237, ENO1P4, AC007279.1, MPP4, RNU6-651P, ALS2, RPS2P16, CDK15, Y_RNA, UBE2V1P11, RNU6-440P.
- chr2:218,326,889–219,015,721, 38 genes, copy number 9–10 (within-gene range 4–10): CATIP-AS2, MIR6810, RPL19P5, CATIP, CATIP-AS1, SLC11A1, CTDSP1, AC021016.2, MIR26B, VIL1, USP37, RN7SKP38, CNOT9, RNU6-136P, PLCD4, ZNF142, BCS1L, RNF25, STK36, TTLL4, CYP27A1, AC009974.2, AC009974.1, PRKAG3, MIR9500, RPL23AP31, WNT6, WNT10A, LINC01494, RNU6-642P, AC097468.2, KRT8P30, CDK5R2, LINC00608, FEV, CRYBA2, MIR375, AC097468.1.
- chr2:225,010,461–227,325,711, 16 genes, copy number 9 (within-gene range 8–9): MIR4439, NYAP2, AC016717.1, AC016717.2, AC016717.3, AC068138.1, AC062015.1, MIR5702, IRS1, AC010735.2, AC010735.1, RHBDD1, AC073149.1, COL4A4, COL4A3, MFF-DT.
- chr2:227,683,763–228,181,687, 13 genes, copy number 9 (within-gene range 4–9): SLC19A3, SCYGR6, SCYGR7, SCYGR8, RNA5SP121, SNRPGP8, AC073065.1, CCL20, TDGF1P2, DAW1, AC073065.2, SPHKAP, RNU6-624P.
- chr2:231,585,864–232,387,457, 24 genes, copy number 9: RPL23AP26, AC104634.1, TEX44, RN7SL499P, PTMA, U4, MIR1244-1, PDE6D, AC073476.3, COPS7B, RPL28P2, AC073476.2, AC073476.1, MIR1471, NPPC, DIS3L2, AC019130.1, MIR562, NRBF2P6, ECEL1P3, AC068134.3, ALPP, AC068134.1, ECEL1P2.
- chr3:6,490,460–7,790,482, 9 genes, copy number 9 (within-gene range 8–9): AC069277.1, GRM7-AS3, AC069277.2, GRM7, MRPS36P1, GRM7-AS2, AC066585.1, GRM7-AS1, AC077690.1.
- chr3:11,060,973–11,846,919, 12 genes, copy number 9: AC066580.1, HRH1, AC083855.2, CHCHD4P4, ATG7, AC083855.1, AC026185.1, AC022001.1, VGLL4, AC022001.2, AC022001.3, TAMM41.
- chr3:12,153,068–12,788,671, 15 genes, copy number 9: TIMP4, MTCO1P5, GSTM5P1, PPARG, AC091492.1, TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17.
- chr3:37,861,880–38,143,022, 10 genes, copy number 9 (within-gene range 4–9): CTDSPL, MIR26A1, VILL, PLCD1, Y_RNA, DLEC1, PPP2R2DP1, ACAA1, Y_RNA, MYD88.
- chr3:96,244,732–96,814,407, 10 genes, copy number 10: AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1.
- chr3:99,802,699–100,577,444, 13 genes, copy number 9: AC069222.1, CMSS1, FILIP1L, MIR3921, AC129803.1, TMEM30CP, DUSP12P1, VTI1BP1, TBC1D23, NIT2, TOMM70, LNP1, TMEM45A.
- chr3:161,426,427–162,601,792, 8 genes, copy number 10: LINC02067, AC112491.1, RPL23AP42, OTOL1, AC112770.1, AC131211.1, TOMM22P6, AC128716.1.
- chr3:172,039,578–172,725,038, 14 genes, copy number 9 (within-gene range 4–9): FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2.
- chr3:176,068,042–177,228,000, 12 genes, copy number 10 (within-gene range 5–10): EI24P1, AC104640.2, AC117434.1, LINC01208, MIR7977, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P.
- chr3:178,164,008–180,037,053, 34 genes, copy number 10 (within-gene range 5–10): AC117453.1, KCNMB2, AC117457.1, LINC01014, RNA5SP148, PPIAP75, KCNMB2-AS1, ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1, ZNF639, AC007823.1, MFN1, GNB4, AC007620.2, AC007620.3, AC007620.1, MTHFD2P7, ACTL6A, AC090425.3, AC090425.2, MRPL47, NDUFB5, AC090425.1, H3P13, USP13, PEX5L, AC007687.1, PEX5L-AS1, PEX5L-AS2.
- chr5:22,139,247–24,353,443, 20 genes, copy number 9: AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1.
- chr6:45,880,827–46,606,162, 9 genes, copy number 9 (within-gene range 4–9): CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1.
- chr6:49,785,660–50,637,205, 12 genes, copy number 10: PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1, AL132799.1, AL360175.1, AL135908.1.
- chr8:46,028,804–138,497,261, 1,320 genes, copy number 10–11 (broad region; genes not listed).
- chr9:74,980,790–75,198,177, 7 genes, copy number 9: CARNMT1, AL158825.2, AL158825.3, NMRK1, OSTF1, Y_RNA, RNU6-1228P.
- chr9:92,000,087–92,325,636, 19 genes, copy number 9: SPTLC1, AL391219.1, HSPE1P22, AL354751.3, MTATP6P29, MTCO3P29, MTND3P23, MTND4LP7, MTND4P15, AL354751.1, LINC00475, AL354751.2, BEND3P2, PRSS47, AL136097.2, IARS1, MIR3651, SNORA84, NOL8.
- chr9:104,781,006–105,776,629, 15 genes, copy number 9 (within-gene range 6–9): ABCA1, AL359182.1, CT70, AL591506.1, RN7SKP191, SLC44A1, FSD1L, RALGAPA1P1, AL158070.1, FKTN, AL158070.2, TAL2, TMEM38B, AL592437.1, DEPDC1P2.
- chr9:114,850,968–115,744,330, 7 genes, copy number 9 (within-gene range 4–9): DELEC1, TNFSF8, TNC, AL162425.1, AL355601.1, AL691420.1, U2.
- chr14:24,352,057–37,596,059, 208 genes, copy number 9–12 (broad region; genes not listed).
- chr17:15,379,864–16,218,185, 43 genes, copy number 9: AC005703.3, RN7SL792P, CDRT4, TVP23C-CDRT4, RPL9P2, TVP23C, PPIAP53, AC005838.2, CDRT1, AC005324.2, SNORA74, AC005838.1, TRIM16, AC005324.4, ZNF29P, ZNF286A, AC005324.3, UBE2SP1, TBC1D26, TBC1D26-AS1, AC005324.5, AC005324.1, CDRT15P2, ZSWIM5P1, RNA5SP436, IL6STP1, MEIS3P1, AC015922.2, AC015922.3, AC015922.1, LINC02087, SPECC1P1, ADORA2B, ZSWIM7, TTC19, AC002553.2, NCOR1, AC002553.1, RPLP1P11, RPL22P21, RNU6-314P, RNU6-862P, RN7SL442P.
- chr17:20,290,257–20,483,991, 13 genes, copy number 9: RNU6-1057P, CCDC144CP, RNU6-467P, AC008088.1, Metazoa_SRP, UPF3AP2, USP32P3, SRP68P3, AC015818.9, AC015818.10, NOS2P3, LGALS9B, TNPO1P3.
- chr18:2,655,726–3,013,144, 10 genes, copy number 9 (within-gene range 6–9): SMCHD1, AP001011.1, Y_RNA, EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4.
- chr18:25,818,234–26,438,041, 13 genes, copy number 9: RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543.

Autosomal genes at a single copy (total copy number 1): 677. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
